Somatic mutation profile of tumor specimen TCGA-XU-A92W-01A (aliquot TCGA-XU-A92W-01A-11D-A423-09) from TCGA case TCGA-XU-A92W, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 61.7 years (22,554 days).
Specimen TCGA-XU-A92W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ea2b1fa-9eae-4055-b02e-78b93fdda2cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92W-10A (Blood Derived Normal), aliquot TCGA-XU-A92W-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f18b725f-b9de-481c-b887-14ea0d32ad8b

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNC1 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1477026732; called by muse, mutect2
- MAEL | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1411103872; called by muse, mutect2
- OR8B4 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.285); catalogued as COSV62069762, COSV62070063; called by muse, mutect2
- SPTBN5 | c.4232G>A p.R1411H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs181128984; called by mutect2, varscan2
- AGPS | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2
- BAG4 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); called by muse, mutect2
- PLEKHG7 | c.1686C>A p.L562= | Silent (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- SERPINB1 | c.12G>A p.L4= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- BCAS3 | c.2075-4804C>T | Intron (SNP) | VAF 8/76 reads (11%) | catalogued as COSV66774512; called by muse, mutect2, varscan2
- FAM74A3 | n.78A>G | RNA (SNP) | VAF 12/185 reads (6%) | called by mutect2, varscan2
